Somatic mutation profile of tumor specimen TCGA-12-0670-01B (aliquot TCGA-12-0670-01B-01W-0424-08) from TCGA case TCGA-12-0670, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.8 years (22,189 days).
Specimen TCGA-12-0670-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73947d23-db66-41cd-9c98-9335e8a94b96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0670-10B (Blood Derived Normal), aliquot TCGA-12-0670-10B-01W-0424-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4896a6c-3156-4948-bed8-68df6efb4120

The open-access MAF lists 64 somatic variants for this specimen: 42 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 35, Silent 22, Frame Shift Ins 4, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.787A>C p.T263P | Missense Mutation (SNP) | VAF 2382/3407 reads (70%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.236); catalogued as rs1057519829, COSV51768130; ClinVar: likely pathogenic; called by mutect2, varscan2
- FBN1 | c.538+2T>C p.X180_splice | Splice Site (SNP) | VAF 18/101 reads (18%) | catalogued as rs1555404799, COSV100356010; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP2C2 | c.162dup p.K55Qfs*39 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs1170087721; called by pindel, varscan2
- C19orf57 | c.35A>G p.E12G | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV60968572; called by muse, mutect2, varscan2
- CD38 | c.732T>A p.H244Q | Missense Mutation (SNP) | VAF 140/375 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV56890808; called by muse, mutect2, varscan2
- CIT | c.646G>C p.G216R | Missense Mutation (SNP) | VAF 55/558 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV99950476; called by muse, mutect2, varscan2
- CLCNKB | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as rs140923370; called by muse, mutect2, varscan2
- DBH | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs766166337, COSV55039535; called by muse, mutect2, varscan2
- DYSF | c.5946+2T>C p.X1982_splice | Splice Site (SNP) | VAF 37/61 reads (61%) | catalogued as COSV50416999; called by muse, mutect2, varscan2
- EMC6 | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV50265085; called by muse, mutect2, varscan2
- FAM184A | c.2105A>G p.Q702R | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs780011609, COSV58854939; called by muse, varscan2
- FBN3 | c.2089G>A p.V697M | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as rs764671280, COSV54462797; called by muse, mutect2, varscan2
- GABRA6 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs377498858; called by muse, mutect2, varscan2
- GABRR2 | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as rs369596214; called by muse, varscan2
- GRIN2B | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 368/983 reads (37%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.726); catalogued as rs201377003, COSV74205072; ClinVar: likely benign; called by muse, mutect2, varscan2
- HEATR4 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs765437480, COSV58573076; called by muse, mutect2, varscan2
- HYAL1 | c.734G>C p.S245T | Missense Mutation (SNP) | VAF 68/128 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56498113; called by muse, mutect2, varscan2
- KIAA1755 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.162); catalogued as COSV54073701; called by muse, mutect2, varscan2
- LRFN5 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 92/234 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as rs138417169, COSV53241711; called by muse, mutect2, varscan2
- MAGI3 | c.1495G>T p.D499Y | Missense Mutation (SNP) | VAF 169/380 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56836947; called by muse, mutect2, varscan2
- MUC16 | c.27793G>A p.V9265I | Missense Mutation (SNP) | VAF 166/568 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.162); catalogued as rs777203248, COSV101199917; called by muse, mutect2, varscan2
- MUC16 | c.21439C>A p.L7147I | Missense Mutation (SNP) | VAF 116/411 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV101200676, COSV67479821; called by muse, mutect2, varscan2
- OR2T33 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.021); catalogued as rs374091097; called by mutect2, varscan2
- OTUD4 | c.1686G>C p.K562N (on ENST00000447906 / NM_001366057.1; = p.K497N on NM_001102653.1) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV71381923; called by muse, mutect2, varscan2
- PCYT2 | c.195C>A p.H65Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV58711454; called by muse, mutect2, varscan2
- PEAK1 | c.2560T>A p.S854T | Missense Mutation (SNP) | VAF 318/721 reads (44%) | SIFT tolerated (0.97); PolyPhen benign (0.01); catalogued as COSV56936828; called by muse, mutect2, varscan2
- PIK3R5 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs370330027; called by muse, mutect2, varscan2
- PPP2R3A | c.760A>T p.I254L | Missense Mutation (SNP) | VAF 121/269 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV53864695; called by muse, mutect2, varscan2
- PTGIS | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 15/605 reads (2%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV99721213; called by muse, mutect2
- RXFP3 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57506028, COSV57507322; called by muse, mutect2, varscan2
- SAMSN1 | c.344C>G p.T115R | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.588); catalogued as COSV53472434; called by muse, mutect2, varscan2
- SECISBP2L | c.1393A>G p.I465V (on ENST00000559471 / NM_001193489.2; = p.I420V on NM_014701.4) | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.402); catalogued as COSV55935022; called by muse, mutect2, varscan2
- SIGLEC9 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs76493296, COSV51584887; called by muse, mutect2, varscan2
- SP100 | c.1689C>A p.N563K | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as COSV50981879; called by muse, mutect2, varscan2
- SRGAP3 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1328984631, COSV64534099; called by muse, mutect2, varscan2
- TRPM2 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs764168148, COSV55966647; called by mutect2, varscan2
- VILL | c.463T>A p.W155R | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52185201; called by muse, mutect2, varscan2
- ZFP42 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1052462774, COSV58817514; called by muse, mutect2, varscan2
- AMD1 | c.20dup p.E8Rfs*32 | Frame Shift Ins (INS) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- GHRH | c.193del p.S65Afs*15 | Frame Shift Del (DEL) | VAF 252/1049 reads (24%) | called by mutect2, pindel, varscan2
- KIDINS220 | c.966dup p.Q323Tfs*5 | Frame Shift Ins (INS) | VAF 26/70 reads (37%) | called by mutect2, pindel, varscan2
- MICAL3 | c.5116dup p.R1706Pfs*101 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel
- ADAMTS12 | c.3096G>A p.L1032= | Silent (SNP) | VAF 105/370 reads (28%) | catalogued as COSV61264660; called by muse, mutect2, varscan2
- ADAMTS18 | c.3393G>A p.P1131= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as rs753902193, COSV51415920; called by muse, mutect2, varscan2
- ADGRF4 | c.1299G>A p.T433= | Silent (SNP) | VAF 130/346 reads (38%) | catalogued as rs147818832, COSV99348323; called by muse, mutect2, varscan2
- ALPK2 | c.6270C>T p.D2090= | Silent (SNP) | VAF 528/1376 reads (38%) | catalogued as rs146778283; called by muse, varscan2
- DHCR24 | c.1209C>T p.N403= | Silent (SNP) | VAF 54/122 reads (44%) | catalogued as rs566854149, COSV64874143; ClinVar: likely benign; called by muse, mutect2, varscan2
- FANCM | c.2202T>C p.S734= | Silent (SNP) | VAF 49/173 reads (28%) | catalogued as COSV57502019; called by muse, mutect2, varscan2
- GALNT17 | c.714C>T p.T238= | Silent (SNP) | VAF 43/494 reads (9%) | catalogued as rs758291046, COSV61146047; called by muse, mutect2
- HTR2C | c.420G>A p.A140= | Silent (SNP) | VAF 58/69 reads (84%) | catalogued as rs200457900, COSV52213029; called by muse, mutect2, varscan2
- INTS6L | c.1065T>C p.F355= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100878231; called by muse, mutect2, varscan2
- JPH1 | c.612G>A p.A204= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs771740296, COSV100646575; called by muse, varscan2
- KIAA1755 | c.2562C>T p.S854= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as rs143020541; called by muse, mutect2, varscan2
- KLF8 | c.858C>A p.T286= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV63847989; called by muse, mutect2, varscan2
- LCT | c.3717G>A p.S1239= | Silent (SNP) | VAF 137/289 reads (47%) | catalogued as rs151165674, COSV51554234; called by muse, mutect2, varscan2
- MANEA | c.1167A>T p.A389= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV62589781; called by muse, mutect2, varscan2
- NEK10 | c.2643C>T p.D881= | Silent (SNP) | VAF 133/315 reads (42%) | catalogued as rs753032028, COSV55356888; called by muse, mutect2, varscan2
- NOTCH3 | c.2451C>T p.P817= | Silent (SNP) | VAF 87/257 reads (34%) | catalogued as rs757662917, COSV54636814; called by muse, varscan2
- NPR1 | c.2040G>A p.G680= | Silent (SNP) | VAF 967/2178 reads (44%) | catalogued as COSV64117663; called by muse, mutect2, varscan2
- PLA2G15 | c.696C>T p.G232= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs202175010, COSV99547319; called by muse, mutect2
- PLCG2 | c.2103C>T p.H701= | Silent (SNP) | VAF 190/433 reads (44%) | catalogued as COSV63870419; called by muse, mutect2, varscan2
- TBX21 | c.1131G>A p.A377= | Silent (SNP) | VAF 73/151 reads (48%) | catalogued as rs1011851262, COSV51596523; called by muse, mutect2, varscan2
- TIAM1 | c.3165C>T p.Y1055= | Silent (SNP) | VAF 63/136 reads (46%) | catalogued as rs373676358; called by muse, mutect2, varscan2
- TNFRSF11B | c.846G>A p.Q282= | Silent (SNP) | VAF 134/322 reads (42%) | catalogued as COSV52071590; called by muse, mutect2, varscan2
